Surgical pathology report (de-identified scan), TCGA case TCGA-IR-A3L7, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-IR-A3L7-01A (Primary Tumor).

[page 1 of 2]
Specimens Submitted:

- 1: SP: Radical hysterectomy - uterus and cervix (fs)
- 2: SP: Left external iliac nodes
- 3: SP: Left hypogastric nodes
- 4: SP: Left obturator nodes
- 5: SP: Rt external iliac lymph node (
- 6: SP: Rt hypogastric lymph node
- 7: SP: Rt obturator lymph node

DIAGNOSIS:

- 1) UTERUS AND CERVIX; TOTAL HYSTERECTOMY:
- INVASIVE SQUAMOUS CELL CARCINOMA OF UTERINE CERVIX WITH FOCAL ADENOID AND BASALOID FEATURES, POORLY DIFFERENTIATED. THE MAXIMAL THICKNESS OF THE CERVICAL STROMAL INVASION IS 22 MM. THE THICKNESS OF THE CERVIX IN THE AREA OF MAXIMAL TUMOR INVASION IS 23 MM. NO EVIDENCE OF TUMOR MULTICENTRICITY IS IDENTIFIED. IN SITU CARCINOMA IS ALSO PRESENT, FOCALLY INVOLVING ENDOCERVICAL GLANDS. VASCULAR INVASION IS PRESENT. PERINEURIAL INVASION IS PRESENT. NO VAGINAL EXTENSION IS IDENTIFIED. THE TUMOR DOES NOT EXTEND INTO UTERINE CORPUS. NO PARAMETRIAL INVOLVEMENT IS IDENTIFIED. ALL SURGICAL MARGINS ARE FREE OF TUMOR, HOWEVER, CARCINOMA EXTENDS TO WITHIN 0.1 CM OF THE DEEP PARAMETRIAL SOFT TISSUE MARGIN OF RESECTION AT 9:00, AND WITHIN 0.1 CM OF THE ECTOCERVICAL MARGIN OF RESECTION. THE ENDOMETRIUM SHOWS THE FOLLOWING ABNORMALITY(IES): POLYP(S). THE MYOMETRIUM IS UNREMARKABLE.
- 2) LYMPH NODES, LEFT EXTERNAL ILIAC; EXCISION:
- FOUR BENIGN LYMPH NODES (0/4).
- 3) LYMPH NODES, LEFT HYPOGASTRIC; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 4) LYMPH NODES, LEFT OBTURATOR; EXCISION:
- SIX BENIGN LYMPH NODES (0/6).
- 5) LYMPH NODES, RIGHT EXTERNAL ILIAC; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).

ICD-0-3

carcinoma, squamous cell, 8070/3
Site: cervix, NOS c53.9

PATH
REPORT
11

** Continued on next page **

[page 2 of 2]
[REDACTED]

6) LYMPH NODE, RIGHT HYPOGASTRIC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).

7) LYMPH NODES, RIGHT OBTURATOR; EXCISION:
- FOUR BENIGN LYMPH NODES (0/4).

[REDACTED]

** Report Electronically Signed Out **

[REDACTED]

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION
OF THE SLIDES (AND/OR OTHER
MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

Source: NCI Genomic Data Commons file edc5cdef-15b6-4e79-9549-f1f76d5a9984 (TCGA-IR-A3L7.411A8FF2-4778-43AD-99F7-FD5BD23559DD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).